Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A0CV, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A0CV-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

Patient:
FMP/SSN:
DOB/Age/Sex:
Location:
Physician(s):

Specimen #:
Taken:
Received:
Reported:

Sex: F Race: ASIAN - PACIFIC ISLANDER

SPECIMEN:

- A: SENTINEL LYMPH NODE #1 LEFT
- B: NON SENTINEL LYMPH NODE LEFT
- C: LEFT BREAST AND AXILLARY CONTENT

100-0-3

Carcinoma, infiltrating ductal, NOS 8500/3
Site: breast, NOS C50.9

FINAL DIAGNOSIS:

1/25/11 *kw*

A-C. BREAST, LEFT, MASTECTOMY WITH AXILLARY AND SENTINEL LYMPH NODES:
TUMOR TYPE:
INVASIVE DUCTAL CARCINOMA WITH AN EXTENSIVE INTRADUCTAL COMPONENT
(70-80% intraductal tumor largely intermixed with invasive)
NOTTINGHAM GRADE: GRADE II (MODERATELY DIFFERENTIATED)
NOTTINGHAM SCORE: 6
(Tubules= 2, Nuclei= 3, Mitoses= 1; mitotic count <1 per 10 HPF)
TUMOR SIZE (GREATEST DIMENSION): 4.1 CM (MEASURED GROSSLY).
TUMOR NECROSIS: NOT IDENTIFIED.
MICROCALCIFICATIONS:
PRESENT IN INVASIVE AND IN SITU TUMOR AND IN BENIGN DUCTS
VENOUS / LYMPHATIC INVASION: PRESENT
MARGINS: NEGATIVE
NEAREST MARGIN, INVASIVE TUMOR: 2.5 MM (DEEP, SLIDE C6)
NEAREST MARGIN, IN-SITU TUMOR: 3 MM (DEEP, SLIDE C6)
INTRADUCTAL COMPONENT: DUCTAL CARCINOMA IN SITU, CRIBRIFORM TYPE
NUCLEAR GRADE: 3
LYMPH NODES: METASTASIS IN TWO OF EIGHTEEN (2/18) EXAMINED LYMPH NODES
ONE (1) SENTINEL LYMPH NODE (SPECIMEN A): POSITIVE
- EXTRANODAL EXTENSION: PRESENT, 4 MM
ONE (1) LYMPH NODE (SPECIMEN C, LOW, C12): POSITIVE
- EXTRANODAL EXTENSION: PRESENT, 1 MM
NIPPLE INVOLVEMENT: NOT IDENTIFIED.
SKIN INVOLVEMENT: NOT IDENTIFIED.
MULTICENTRICITY: NOT PRESENT.
ESTROGEN, PROGESTERONE RECEPTOR STATUS AND HER 2 NEU WERE REPORTED
PREVIOUSLY IN SURGICAL CASE
PATHOLOGIC STAGE: pT2N1aMX
ADDITIONAL PATHOLOGIC CHANGES:
COLUMNAR CELL CHANGE WITH ATYPIA
SCLEROSING ADENOSIS
FIBROCYSTIC CHANGES, USUAL DUCTAL HYPERPLASIA, FIBROADENOMA

COMMENT:

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Patient:

Specimen #:

FINAL DIAGNOSIS (continued):

The earlier report, of a core biopsy indicates hormone receptors are POSITIVE (100% strong staining for both estrogen and progesterone receptors) and Her2 by immunohistochemistry is NEGATIVE (1+).

** Report Electronically Signed Out **

CLINICAL DIAGNOSIS AND HISTORY:

year old with left breast 4 X 4 cm mass in left upper outer quadrant detected with 1cm lymph node

PRE-OPERATIVE DIAGNOSIS:
left breast cancer

POST-OPERATIVE DIAGNOSIS:
same

FROZEN SECTION DIAGNOSIS:

SPECIMEN TYPE: LYMPH NODE

TIME RECEIVED:

TIME REPORTED:

REPORTED TO: DR.

REPORTED BY: DR.

BLOCKS: 2

SCRAPE PREPS: 2

FROZEN SECTION DIAGNOSIS: POSITIVE FOR METASTATIC CARCINOMA.

GROSS DESCRIPTION:

- A. Received fresh for intraoperative consultation labeled with patient's name designated "SENTINEL NODE #1 COUNT 104" consists of a 1.0 x 0.8 x 0.5 cm very firm lymph node with homogeneous yellow tan cut surface. Touch preps are prepared. Half of node submitted for CBCP protocol and remaining half submitted for paraffin section.
- B. Received fresh labeled with the patient's name designated "NON-SENTINEL LYMPH NODE LEFT" is tan pink soft tissue measuring 0.7 x 0.5 x 0.2 cm. The presumed lymph node is bisected and submitted entirely.

. Received fresh labeled with patient's name

designated "BREAST

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

Patient:

Specimen #:

GROSS DESCRIPTION (continued):

AND AXILLARY CONTENTS" consists of 380 gram left mastectomy oriented with single stitch medial, two stitches superior, stitch on highest axillary portion. Specimen measures 23 cm medial to lateral 15 cm superior to inferior, 3 cm anterior to posterior. Attached skin ellipse displays a centrally located everted nipple measuring 1 cm. No discharge is identified. No scars are identified.

There is a well-defined pink white firm gritty mass in the left outer quadrant measuring 4.1 x 3.5 x 1.5 cm. Tissue surrounding the mass is remarkably nodular and firm with possible superior extension of primary lesion to approximately 5 cm (C4). Focal hemorrhage consistent with previous biopsy is also noted. Remaining quadrants are also composed of remarkably nodular focally indurated dense fibrous tissue. No additional masses identified. Fatty tissue comprises 20% of specimen and is unremarkable.

The attached axillary tail measures 9 x 3.5 x 1.5 cm. Sectioning reveals sixteen lymph nodes ranging from 0.5 x 0.7 cm in greatest dimension. Sectioning of lowest lymph node shows a firm pink white cut surface with possible involvement by lesion.

INK KEY:

blue: superficial
black: deep

SUMMARY OF SECTIONS:

- C1: skin
- C2: lower outer quadrant mass
- C3: margin of C2
- C4: possible extension of tumor
- C5: margin of C4
- C6: mass with deep margin
- C7: additional mass
- C8: lower outer quadrant
- C9: upper outer quadrant
- C10: upper inner quadrant
- C11: lower inner quadrant
- C12: one low lymph node
- C13: two low bisected lymph nodes, one inked blue
- C14: three low lymph nodes
- C15: one high lymph node
- C16: two high lymph nodes bisected, one blue
- C17: one high lymph node intact.
- Matched sections of C1 C7-C12 and C15 are submitted in OCT for CBCP protocol.

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

Patient:

Specimen #: -

GROSS DESCRIPTION (continued):

- C18: nipple
- C19: mass with deep margin
- C20: mass with deep and superficial margin
- C21: six additional lymph nodes. 21CF

Dual/Synchronous Pathology Method		/

Source: NCI Genomic Data Commons file 6c851f95-564c-4a79-94c2-ffa75e74611c (TCGA-A2-A0CV.FBDDD9EE-0A5C-4CAB-9EB3-48B6431A9A84.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).